Surgical pathology report (de-identified scan), TCGA case TCGA-DK-AA75, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DK-AA75-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY REPORT

Patient Name:

Med. Rec. #:

DOB: (Age

Gender: M

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Clinical Diagnosis & History:

Muscle invasive TCC.

Specimens Submitted:

1: Bladder, prostate, seminal vesicles, peri- vesicle node; radical prostatectomy

2: Ureter, left distal; excision

3: Ureter, right distal; excision

4: Ureter, right distal, #2; excision

DIAGNOSIS:

1. **Bladder, prostate, seminal vesicles, peri- vesicle node; radical prostatectomy:**

a.

Tumor Type:

Urothelial carcinoma with mixed histologic features, including: predominantly micropapillary with focal NOS

components

Histologic Grade:

High grade

Pattern of growth of the Non-Invasive component:

Papillary and flat

with focal micropapillary features

Pattern of growth of the Invasive component:

Infiltrating

Tumor Multicentricity:

Identified

In situ carcinoma is also multifocal and extensive

Bladder Local Invasion:

Perivesical soft tissues

Perivesical involvement is extensive

Extravesical Tumor Extension:

Ureters uninvolved

Urethra uninvolved

Right ureteral orifice involved by in situ carcinoma

Vascular Invasion:

Identified

Lymphovascular invasion is extensive

Perineural Invasion:

Identified

Surgical Margins:

Free of tumor

Non-Neoplastic Mucosa:

Unremarkable

Prostate:

Other Please see part b

Seminal Vesicles:

Not involved

Perivesical Lymph Nodes:

Pw TSS, TCGA tumor = pure urothelial.

ICD O-3

Carcinoma, urothelial NOS

8/20/13

Site: 4 Bladder, anterior wall

0673

4/30/14

[page 2 of 5]
SURGICAL PATHOLOGY REPORT

Metastatic carcinoma present in 4/6 nodes
Extracapsular extension is present
The Pathologic Stage is (AJCC 2002):
pT3 (Invasion of perivesicle soft tissue)

PR0 (No involvement of prostate)

b.

Tumor Type:

Adenocarcinoma

Gleason's Grade:

Primary Gleason grade:3

Secondary Gleason grade:4

Total Gleason score:7

Tumor Location:

Involves Right anterior

The focus of carcinoma is minute

Vascular Invasion:

Not Identified

Perineural Invasion:

Identified

Tumor Multicentricity:

Not identified

High Grade Prostatic Intraepithelial Neoplasia:

Identified

Capsule:

Tumor confined to prostate

Seminal Vesicles:

Not involved

Bladder Neck:

Not Involved

Surgical Margins:

Free of tumor

Non-Neoplastic Prostate:

Exhibits nodular hyperplasia

Staging (AJCC 1997):

pT2a (confined to the prostate & capsule, involving one lobe)

2. Ureter, left distal; excision:
- Benign segment of ureter
3. Ureter, right distal; excision:
- Benign segment of ureter
4. Ureter, right distal, #2; excision:
- Benign segment of ureter

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[page 3 of 5]
SURGICAL PATHOLOGY REPORT

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received fresh, labeled "Bladder, prostate, seminal vesicles, peri-vesicles node". It consists of a cystectomy specimen measuring 12.0 cm from superior to inferior, 10.0 cm laterally and 6.0 cm from anterior to posterior. The bladder measures 8.0 x 8.0 x 4.0 cm, the prostate measures 4.0 x 4.0 x 4.0 cm, the right seminal vesicle measures 4.5 x 2.5 x 0.5 cm, the right vas deferens measures 8.0 cm in length x 0.2 cm in diameter, the left seminal vesicle measures 4.5 x 1.5 x 0.6 cm, and the left vas deferens measures 7.8 cm in length x 0.2 cm in diameter. The anterior aspect of the bladder is inked blue and the posterior black. The prostatic urethral margin is shaved and submitted. The bladder is opened along the anterior midline to reveal a white-tan papillary mass measuring 4.5 x 4.0 cm which is grossly involving the left and right anterior wall and grossly appears to extend to the dome. The mass lies 5.5 cm from the left ureteral orifice and 5.3 cm from the right ureteral orifice. Both ureters are probed patent measuring up to 0.2 cm in maximum diameter. The lesion is sectioned to reveal a white firm cut surface and extending to a depth of 4.2 cm. The mass is 0.2 cm from the inked fat. There is a scar noted on the left posterior wall measuring 1.5 x 0.3 cm, located 3.0 cm from the left ureteral orifice and 4.5 cm from the right ureteral orifice. In addition, there is a white-tan firm scarred area noted on the right posterior wall measuring 0.5 x 0.3 cm, located 3.5 cm from the left ureteral orifice and 1.5 cm from the right ureteral orifice. The posterior bladder mucosa is red-brown, congested with ill-defined areas of nodularity. Discrete perivesical lymph nodes are grossly identified. The prostate is serially sectioned to reveal a diffuse firm parenchyma with a white-tan whorled appearance. There are several white nodules noted ranging from 0.2 to 0.6 cm in diameter and multiple cysts ranging from 0.1 to 0.2 cm in diameter. Representative sections are submitted including three sections from each prostatic quadrant and transition zone. TPS is submitted.

Summary of sections:

UM - urethral margin

RUM - right ureter margin

LUM - left ureter margin

RUO - right ureter orifice

LUO - left ureter orifice

AWL1-2 - full face section of anterior wall lesion with deepest invasion

WM - full face section of anterior wall lesion with deepest invasion, whole mount

LPL - left posterior wall lesion

RPL - right posterior wall lesion

LPW - left posterior wall

LAW - left anterior wall

RPW - right posterior wall

RAW - right anterior wall

TRI - trigone

DOM - dome

APWS - additional sections of posterior wall

F - peri-vesical fat

RSV - right seminal vesicle

LSV - left seminal vesicle

RAP - right apex prostate

LAP - left apex prostate

RAM - right anterior mid prostate

RPM - right posterior mid prostate

LAM - left anterior mid prostate

LPM - left posterior mid prostate

RAB - right anterior base prostate

RPB - right posterior base prostate

LAB - left anterior base prostate

LPB - left posterior base prostate

LN - whole lymph nodes

BLN - bisected lymph nodes (one lymph node per cassette)

TLN - trisected lymph node

[page 4 of 5]
SURGICAL PATHOLOGY REPORT

2) The specimen is received in formalin, labeled, "Left distal ureter, clip is on proximal margin", and consists of a tan tubular piece of tissue measuring 3.5 cm in length x 0.3 cm in diameter with surrounding yellow fatty tissue averaging 0.5 cm in thickness. There is an attached clip on the proximal margin. The proximal margin is inked red and the distal margin is inked black. The tissue is serially sectioned and entirely submitted.

Summary of sections:

E – ends (red-proximal margin; black-distal margin)

M – middle

3) The specimen is received in formalin, labeled, "Right distal ureter, clip is on proximal margin", and consists of a tan tubular piece of tissue measuring 1.2 cm in length x 0.3 cm in diameter with surrounding yellow fatty tissue averaging 0.5 cm in thickness. There is an attached clip on the proximal margin. The proximal margin is inked red and the distal margin is inked black. The tissue is serially sectioned and entirely submitted.

Summary of sections:

E – ends (red-proximal margin; black-distal margin)

M – middle

4) The specimen is received in formalin, labeled, "Right distal ureter #2, clip is on high proximal margin", and consists of a tan tubular piece of tissue measuring 1.5 cm in length x 0.3 cm in diameter with surrounding yellow fatty tissue averaging 0.3 cm in thickness. There is an attached clip on the high proximal margin. The high proximal margin is inked red and the distal margin is inked black. The tissue is serially sectioned and entirely submitted.

Summary of sections:

E – ends (red-high proximal margin; black-distal margin)

M – middle

Summary of Sections:

Part 1: Bladder, prostate, seminal vesicles, peri- vesicle node; radical prostatectomy

Blocks	Block Designation	PCs
3	APWS	3
6	AWL1	6
6	AWL2	6
3	BLN	6
2	DOM	2
1	F	2
2	LAB	2
2	LAM	2
1	LAP	1
1	LAW	1
1	LN	2
2	LPB	2
6	LPL	6
1	LPM	1
1	LPW	1
1	LSV	1
1	LUM	1
1	LUO	2
2	RAB	2
2	RAM	2
1	RAP	1
1	RAW	1
2	RPB	2
2	RPL	2
1	RPM	1
1	RPW	1

[page 5 of 5]
SURGICAL PATHOLOGY REPORT

1	RSV	1
1	RUM	1
1	RUO	2
1	TLN	3
1	TRI	1
1	UM	1
1	WM	1

Part 2: Ureter, left distal; excision

Blocks	Block Designation	PCs
1	E	2
2	M	8

Part 3: Ureter, right distal; excision

Blocks	Block Designation	PCs
1	E	2
1	M	2

Part 4: Ureter, right distal, #2; excision

Blocks	Block Designation	PCs
1	E	2
1	M	3

Criteria	hw 2/13/14	Yes	No

Source: NCI Genomic Data Commons file 8fdd7d8e-4dda-4609-a5e6-96ebcd19ff36 (TCGA-DK-AA75.7BC5ECDC-33EB-42AA-AD88-71185A483309.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).